Somatic mutation profile of tumor specimen TCGA-SR-A6MX-06A (aliquot TCGA-SR-A6MX-06A-11D-A35I-08) from TCGA case TCGA-SR-A6MX, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Paraganglioma, malignant; Tissue or organ of origin: Nervous system, NOS; Age at diagnosis: 55.3 years (20,186 days).
Specimen TCGA-SR-A6MX-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 02a95b95-dfed-4f10-b6dc-73f9fd8161c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SR-A6MX-10A (Blood Derived Normal), aliquot TCGA-SR-A6MX-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ccb7010-a0fe-424a-9073-23c821106b55

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 12, Silent 5, Frame Shift Del 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.6875del p.P2292Qfs*28 | Frame Shift Del (DEL) | VAF 43/79 reads (54%) | catalogued as COSV100970927; called by mutect2, pindel, varscan2
- CA12 | c.409G>A p.G137R | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201238727, COSV51606921; called by muse, mutect2, varscan2
- CHST10 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs773239496, COSV51807550, COSV99958862; called by muse, mutect2, varscan2
- CSTB | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as rs147307021; called by muse, mutect2, varscan2
- FKBP9 | c.787G>C p.E263Q | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.175); catalogued as COSV54231290; called by muse, mutect2, varscan2
- GABRA4 | c.966C>A p.F322L | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99974284; called by muse, mutect2, varscan2
- PMF1 | c.134_135del p.F45Sfs*15 | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | catalogued as rs772185695; called by mutect2, pindel, varscan2
- PSG8 | c.406G>C p.G136R | Missense Mutation (SNP) | VAF 110/387 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100125976; called by muse, mutect2, varscan2
- SETD2 | c.6110C>G p.T2037R | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs914740277; called by muse, mutect2, varscan2
- UNC79 | c.7677G>A p.M2559I (on ENST00000393151 / NM_001346218.2; = p.M2382I on NM_020818.5) | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as COSV99825134; called by muse, mutect2
- ZKSCAN5 | c.1792G>A p.V598I | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.87); PolyPhen benign (0.441); catalogued as rs4729542, COSV58742027; called by muse, mutect2, varscan2
- HABP2 | c.835C>G p.Q279E | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC16 | c.37479C>A p.Y12493* | Nonsense Mutation (SNP) | VAF 31/332 reads (9%) | called by muse, mutect2
- TGDS | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRHDE | c.2787T>A p.N929K | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GAA | c.1410C>T p.N470= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as rs886043068, COSV100163641; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- GLI3 | c.4086C>T p.S1362= | Silent (SNP) | VAF 26/52 reads (50%) | called by muse, mutect2, varscan2
- GPR162 | c.1332C>T p.A444= (on ENST00000311268 / NM_019858.2; = p.A160= on NM_014449.2) | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs781834006; called by muse, mutect2, varscan2
- MPDZ | c.2052A>G p.T684= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs1217486746; called by muse, mutect2, varscan2
- PAX1 | c.1098C>T p.P366= | Silent (SNP) | VAF 49/124 reads (40%) | catalogued as rs201381441, COSV68272584; called by muse, mutect2, varscan2
